Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3558, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3558-01A (Primary Tumor).

Diagnosis:

Resected colon (sigma) with tumor-free oral and aboral resection margins, with a stalked, tubular adenoma with severe dysplasia (synonymously: profound intraepithelial neoplasia), including a polypoid, moderately differentiated adenocarcinoma with infiltration of the lamina muscularis propria and not displaying any lymph node metastases in the region (G2, pT2, L0, V0, R0, pN0 0/46).

Source: NCI Genomic Data Commons file 0ab1d375-b16f-491d-a0aa-27ced8b3bb9f (TCGA-AA-3558.AB0CEFCC-B895-4D15-9A5F-844A9E8C4341.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).